Surgical pathology report (de-identified scan), TCGA case TCGA-4K-AA1I, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Proteogenex, Inc., specimen TCGA-4K-AA1I-01A (Primary Tumor).

Age/Sex: years / M

Date:

Procedure: Left orchiectomy

Preoperative diagnosis: TUMOR OF THE LEFT TESTIS

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. LEFT TESTIS

Diagnosis:

1. LEFT TESTIS:

- Seminoma
- Tumor does not invade the tunica albuginea and the epididymis
- Vascular invasion is not present
- Resection margin is free of tumor

Gross description:

1. LEFT TESTIS:

Received fresh, is a left testis 8.0 x 5.0 x 2.5 cm in dimensions with a portion of the spermatic cord 5.0 cm in length. In the testis there is a solid firm whitish-gray tumor 4.5 x 4.0 x 4.0 cm in dimensions.

ICD-O-3

Seminoma NOS 9061/3

Site: Left Testis NOS C62.9

11/27/14

Source: NCI Genomic Data Commons file a9b0d1a0-fdb2-4a37-a175-96d388365868 (TCGA-4K-AA1I.D4025AEB-A558-44BE-9D4F-DE741DDA4290.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).